Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFL, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAFL-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; nonseminoma (EC 100%); diameter 4 cm; tumor confined to the testis:
angioinvasion present; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

ICD O-3
Carcinoma, embryonal NOS
9070/3
Site O Testis NOS
6629
Jan 31/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 65fdb18d-67c1-48a8-bdf0-de7226be674f (TCGA-2G-AAFL.78AFA2AD-0615-48B8-9B23-9D8FE87D6CB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).